MMRF case MMRF_1714 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2dfbd9df-e7df-4bfd-9dff-8b0352763090

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.4 years (19,157 days); ISS stage: I; Days to last known disease status: 1,122 days (3.1 years); Days to last follow up: 1,122 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 74 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 101 days; Days to treatment end: 101 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.906 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 6.77 mmol/L.
- Day 94 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.945 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.915 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.46 µg/mL; Lactate Dehydrogenase 7.67 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.
- Day 166 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 11.8 µkat/L; Hemoglobin 3.97 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 6.77 mmol/L.
- Day 297 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 4.02 mmol/L.
- Day 389 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.
- Day 478 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 6.95 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 13.1 mmol/L.
- Day 562 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 1.85 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 13.6 mmol/L.
- Day 667 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 9.74 mmol/L.
- Day 760 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 21.6 mmol/L.
- Day 849 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 9.06 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.66 mmol/L.
- Day 947 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 3.34 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 7.15 mmol/L.
- Day 1,038 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 9.68 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 1,122 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day -2: Weight: 105 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1714_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1714_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
